Somatic mutation profile of tumor specimen TCGA-BF-AAP4-01A (aliquot TCGA-BF-AAP4-01A-11D-A401-08) from TCGA case TCGA-BF-AAP4, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Epithelioid cell melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 61.1 years (22,303 days).
Specimen TCGA-BF-AAP4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d18ac17b-9280-4f47-a105-48f65abee00e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BF-AAP4-10A (Blood Derived Normal), aliquot TCGA-BF-AAP4-10A-01D-A401-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/508c5123-7442-4eb8-a084-d845dde71203

The open-access MAF lists 969 somatic variants for this specimen: 620 protein-altering or splice-affecting, 324 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 570, Silent 324, Nonsense Mutation 34, Intron 15, Splice Region 7, Frame Shift Del 5, RNA 5, Splice Site 4, 3'UTR 2, 5'UTR 1, 5'Flank 1, 3'Flank 1.

Variants (750 of 969; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 26/51 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TBC1D24 | c.328G>A p.G110S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.894); catalogued as rs747821285, CM140129, COSV99565226; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by mutect2, varscan2
- A1CF | c.1027G>A p.G343R | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1402911693, COSV99257325; called by muse, mutect2, varscan2
- ABCA13 | c.10224G>A p.M3408I | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV101447144, COSV71288448; called by muse, mutect2
- ABCA3 | c.1712G>A p.G571E | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100068975, COSV57049942; called by muse, mutect2, varscan2
- ABCA6 | c.3007C>T p.P1003S | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as COSV52636600; called by muse, mutect2, varscan2
- ABCB5 | c.2284G>A p.E762K (on ENST00000404938 / NM_001163941.2; = p.E317K on NM_178559.6) | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs866674219, COSV99329255; called by muse, mutect2, varscan2
- ABI2 | c.835C>T p.P279S (on ENST00000295851 / NM_001375719.1; = p.P273S on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as rs1437586614, COSV99652143; called by muse, mutect2, varscan2
- ABLIM1 | c.800A>G p.K267R | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.863); catalogued as COSV99522600; called by muse, mutect2, varscan2
- AC006059.2 | c.1884A>G p.I628M | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV100045825; called by muse, mutect2, varscan2
- ACRBP | c.924G>A p.W308* | Nonsense Mutation (SNP) | VAF 25/71 reads (35%) | catalogued as COSV99976244; called by muse, mutect2, varscan2
- ACSM1 | c.874C>T p.H292Y | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.938); catalogued as COSV99533321; called by muse, mutect2, varscan2
- ADAM15 | c.1933C>T p.R645* | Nonsense Mutation (SNP) | VAF 13/20 reads (65%) | catalogued as rs757099799, COSV55125191; called by muse, mutect2, varscan2
- ADAM20 | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.111); catalogued as COSV56456519, COSV99833610; called by muse, mutect2, varscan2
- ADAM20 | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.106); catalogued as rs756980185, COSV56455965, COSV56456123; called by muse, mutect2, varscan2
- ADCY8 | c.2554C>T p.R852W | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53901980; called by muse, mutect2
- ADCY8 | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV99653688; called by muse, mutect2, varscan2
- ADGRL3 | c.2476G>A p.E826K (on ENST00000506720 / NM_001322402.2; = p.E758K on NM_015236.6) | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs371439989; called by muse, mutect2, varscan2
- ADGRV1 | c.16502C>T p.S5501F | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs866464814, COSV67980225; called by muse, mutect2, varscan2
- AHR | c.2438C>T p.A813V | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.025); catalogued as COSV99620123; called by muse, mutect2, varscan2
- AIFM3 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV100104966; called by muse, mutect2, varscan2
- ALLC | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs376178731, COSV52994643; called by muse, mutect2, varscan2
- ALPK2 | c.6502A>T p.K2168* | Nonsense Mutation (SNP) | VAF 8/57 reads (14%) | catalogued as COSV100864718; called by muse, mutect2
- AMD1 | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100924518; called by muse, mutect2, varscan2
- AMY1C | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 32/437 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs748751804, COSV64407770; called by muse, mutect2
- ANAPC4 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs543616759, COSV100193854; called by muse, mutect2, varscan2
- ANK2 | c.3869C>T p.S1290F | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52147707; called by muse, mutect2, varscan2
- ANKRD30A | c.676C>T p.Q226* (on ENST00000611781; = p.Q170* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 24/107 reads (22%) | catalogued as COSV100654223; called by muse, mutect2, varscan2
- ANKRD30A | c.3913G>A p.E1305K (on ENST00000611781; = p.E1249K on NM_052997.2) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.118); catalogued as rs867764777, COSV64614680, COSV64619316; called by muse, mutect2
- ANKRD34B | c.1382C>T p.S461L | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100103608; called by muse, mutect2, varscan2
- AOAH | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99333517; called by muse, mutect2, varscan2
- APOB | c.12617G>A p.G4206E | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99267220; called by muse, mutect2, varscan2
- APOB | c.11182G>A p.D3728N | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.149); catalogued as rs1198549888, COSV51923344; called by muse, mutect2, varscan2
- APOBEC4 | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV100426165; called by muse, mutect2, varscan2
- APOL5 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV50769063; called by muse, mutect2, varscan2
- ARHGAP21 | c.5327C>T p.P1776L | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV100256545; called by muse, mutect2, varscan2
- ARHGAP32 | c.2648T>A p.F883Y (on ENST00000310343 / NM_001378025.1; = p.F534Y on NM_014715.4) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.572); catalogued as COSV100088770; called by muse, mutect2, varscan2
- ARID4A | c.707A>G p.N236S | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200497377, COSV100794564; called by muse, mutect2, varscan2
- ARID5B | c.2612C>T p.P871L | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs865814457, COSV54426357; called by muse, mutect2, varscan2
- ASAP1 | c.3343A>T p.R1115W | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100727669; called by muse, mutect2, varscan2
- ASAP3 | c.2533C>T p.P845S | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.3); catalogued as rs1336756048, COSV100369601; called by muse, mutect2, varscan2
- ASPM | c.9076A>C p.M3026L | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as COSV99660910; called by muse, mutect2, varscan2
- ASTL | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.015); catalogued as rs770500068, COSV100668430; called by muse, mutect2, varscan2
- ATP11C | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs1367437587, COSV100558401; called by muse, mutect2, varscan2
- ATP1A2 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV63405661; called by muse, mutect2
- ATP5MPL | c.150T>C p.A50= | Splice Region (SNP) | VAF 26/54 reads (48%) | catalogued as COSV99743857, COSV99744017; called by muse, mutect2, varscan2
- ATR | c.7681C>T p.P2561S | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100638500; called by muse, mutect2, varscan2
- BAIAP3 | c.1928C>T p.A643V | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs199973519, COSV99136344; called by muse, mutect2, varscan2
- BAX | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.628); catalogued as rs749142585, COSV99509203; called by muse, mutect2, varscan2
- BBOX1 | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs779597028, COSV54191977, COSV99589911; called by muse, mutect2, varscan2
- BCLAF1 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as COSV62143836, COSV62146561; called by muse, mutect2
- BICRAL | c.2650C>T p.H884Y | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.439); catalogued as COSV100018357; called by muse, mutect2, varscan2
- BPIFB2 | c.855G>A p.L285= | Splice Region (SNP) | VAF 5/38 reads (13%) | catalogued as COSV99401596; called by muse, mutect2
- BRI3BP | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV58297551; called by muse, mutect2, varscan2
- BVES | c.646C>T p.Q216* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as COSV100115073; called by muse, mutect2
- C19orf57 | c.904G>A p.G302R | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs529452628, COSV100694818, COSV60968060; called by muse, mutect2, varscan2
- C1orf226 | c.659G>A p.R220K | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs762047926, COSV100908150; called by muse, varscan2
- C2orf16 | c.3433C>T p.L1145F | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV100820926; called by muse, mutect2, varscan2
- C7 | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV100496387; called by muse, mutect2
- CACNA1A | c.5506G>A p.E1836K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746886324, COSV100803027; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1A | c.2320G>T p.A774S | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs376308062, COSV100803029; called by muse, mutect2, varscan2
- CACNA1D | c.5239G>A p.G1747R (on ENST00000350061 / NM_001128840.3; = p.G1767R on NM_000720.4) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV99859530; called by muse, mutect2, varscan2
- CACNA2D2 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs587771507, COSV99818180; called by muse, mutect2, varscan2
- CAPSL | c.195G>A p.M65I | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV68437872; called by muse, mutect2, varscan2
- CARM1 | c.1423A>C p.R475= | Splice Region (SNP) | VAF 6/38 reads (16%) | catalogued as COSV99450278; called by muse, mutect2, varscan2
- CASP10 | c.1075G>A p.G359R (on ENST00000272879 / NM_032974.5; = p.G316R on NM_001230.5) | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99629257; called by muse, mutect2, varscan2
- CASP14 | c.521-1G>A p.X174_splice | Splice Site (SNP) | VAF 16/72 reads (22%) | catalogued as COSV55666024, COSV99693112; called by mutect2, varscan2
- CASZ1 | c.2398C>T p.P800S | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.022); catalogued as rs1296552638, COSV100682018; called by muse, mutect2, varscan2
- CATSPERD | c.841G>A p.G281R | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.363); catalogued as COSV101062563; called by muse, mutect2, varscan2
- CCDC105 | c.602G>A p.W201* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as COSV52965650, COSV99480047; called by muse, mutect2, varscan2
- CCDC173 | c.1517G>A p.G506E | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53646022, COSV99644820; called by muse, mutect2, varscan2
- CCDC27 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.098); catalogued as COSV53900697; called by muse, mutect2, varscan2
- CCDC65 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376676508, COSV56739325; called by muse, mutect2, varscan2
- CCDC8 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV100282144; called by muse, mutect2
- CCM2 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as COSV51850865; called by muse, mutect2
- CCR2 | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as rs762615152, COSV52748217; called by muse, mutect2, varscan2
- CCT8L2 | c.1661G>A p.G554E | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.042); catalogued as COSV100743003, COSV63461651; called by muse, mutect2
- CDH10 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.272); catalogued as COSV52577229, COSV52581224; called by muse, mutect2
- CDKN1A | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV99781659; called by muse, mutect2
- CDRT1 | c.1844C>T p.P615L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV100599952; called by muse, mutect2
- CDRT1 | c.1843C>T p.P615S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV100599955; called by muse, mutect2
- CEACAM4 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782727802, COSV99701164; called by muse, mutect2, varscan2
- CEMIP | c.2165G>A p.G722E | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54994859; called by muse, mutect2, varscan2
- CEP170 | c.2983C>T p.R995C | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60508398; called by muse, mutect2, varscan2
- CES3 | c.1409G>A p.G470D | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as COSV100310015; called by muse, mutect2, varscan2
- CFAP47 | c.4664C>T p.S1555F | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as COSV100545625; called by muse, mutect2, varscan2
- CFAP61 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs115295521, COSV55631172; called by muse, mutect2, varscan2
- CHD6 | c.7337C>T p.P2446L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100951300; called by muse, mutect2, varscan2
- CHGB | c.878C>T p.S293F | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.969); catalogued as COSV100973044; called by muse, mutect2, varscan2
- CLCN4 | c.1898G>A p.G633D | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101073976; called by muse, mutect2, varscan2
- CLDN1 | c.422G>A p.G141D | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99790727; called by muse, mutect2, varscan2
- CLDN16 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99290322; called by muse, mutect2, varscan2
- CLEC14A | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.402); catalogued as COSV60563905; called by muse, mutect2, varscan2
- CLEC3A | c.355G>A p.E119K (on ENST00000651443; = p.E110K on NM_005752.6) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs202038528, COSV55219665, COSV55219802, COSV55220651; called by muse, mutect2, varscan2
- CLEC4F | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1227322426, COSV99713950; called by muse, mutect2, varscan2
- CLIP2 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1554729288, COSV99792083; called by muse, mutect2, varscan2
- CLK2 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs199688580, COSV100751909; called by muse, mutect2, varscan2
- CMBL | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99687202; called by muse, mutect2
- CMTM5 | c.650C>T p.A217V (on ENST00000339180 / NM_001288746.2; = p.A150V on NM_138460.3) | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.242); catalogued as rs770567891, COSV59305924; called by muse, mutect2, varscan2
- CMYA5 | c.2222C>T p.S741L | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs551260526, COSV71405134, COSV71406357; called by muse, mutect2, varscan2
- CNOT11 | c.556T>G p.S186A | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.049); catalogued as COSV99179362; called by muse, mutect2, varscan2
- CNOT8 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99597246; called by muse, mutect2, varscan2
- CNR1 | c.837G>A p.W279* | Nonsense Mutation (SNP) | VAF 3/24 reads (13%) | catalogued as COSV100759314; called by muse, mutect2
- CNTN4 | c.2306C>T p.P769L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV61873273; called by muse, mutect2, varscan2
- CNTN6 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.426); catalogued as COSV100611636, COSV63160502; called by muse, mutect2, varscan2
- COL11A1 | c.4169G>A p.G1390E | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62172317; called by muse, mutect2, varscan2
- COL11A1 | c.3028G>A p.D1010N | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1267946269, COSV62190573; called by muse, mutect2, varscan2
- COL11A2 | c.2009G>A p.G670E (on ENST00000341947 / NM_080680.3; = p.G563E on NM_080679.2) | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100554399; called by muse, mutect2, varscan2
- COL1A2 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.89); catalogued as rs774774401, COSV99800686; called by muse, mutect2, varscan2
- COL21A1 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.023); catalogued as COSV55158678, COSV99777539; called by muse, mutect2, varscan2
- COL24A1 | c.2348G>A p.G783D | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100993842, COSV65307278; called by muse, mutect2, varscan2
- COL3A1 | c.3996G>A p.M1332I | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs1298560479, COSV100483593; called by muse, mutect2, varscan2
- COL4A1 | c.3346G>A p.E1116K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as COSV65426065; called by muse, mutect2, varscan2
- COL4A1 | c.946C>T p.Q316* | Nonsense Mutation (SNP) | VAF 19/52 reads (37%) | catalogued as COSV101011441; called by muse, mutect2, varscan2
- COL4A2 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.237); catalogued as COSV100847448; called by muse, mutect2, varscan2
- COL4A4 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1414074, COSV100307469; called by muse, mutect2, varscan2
- COL4A6 | c.2968G>A p.G990R | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100563477, COSV100564831; called by muse, mutect2, varscan2
- COLEC12 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.012); catalogued as COSV101232134; called by muse, mutect2, varscan2
- COPS7A | c.289C>T p.R97* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as rs1396031595, COSV99976547; called by muse, mutect2, varscan2
- CPLX1 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1423645926, COSV100408392, COSV58375733; called by muse, mutect2
- CPNE9 | c.1097C>T p.S366F | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99808418; called by muse, mutect2, varscan2
- CR1 | c.4614T>G p.F1538L | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100887964, COSV65464314; called by muse, mutect2, varscan2
- CRACDL | c.2707G>A p.E903K | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as COSV101194113; called by muse, mutect2, varscan2
- CREB5 | c.556C>T p.P186S (on ENST00000357727 / NM_182898.4; = p.P179S on NM_004904.3) | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.992); catalogued as rs1200013563, COSV100745272; called by muse, varscan2
- CRTC2 | c.866C>T p.T289I | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1223988351, COSV100339294; called by muse, mutect2, varscan2
- CSF1 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV100294446, COSV100294781; called by muse, mutect2, varscan2
- CSMD3 | c.10120G>A p.V3374I (on ENST00000297405 / NM_001363185.1; = p.V3205I on NM_052900.3) | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs201296258, COSV99843806; called by muse, mutect2, varscan2
- CSMD3 | c.5822G>A p.G1941E (on ENST00000297405 / NM_001363185.1; = p.G1837E on NM_052900.3) | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52289908; called by muse, mutect2
- CSPP1 | c.949C>T p.R317C (on ENST00000676605; = p.R276C on NM_024790.6) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.111); catalogued as rs114953032, COSV51584805; called by muse, mutect2, varscan2
- CTAGE1 | c.1459C>T p.P487S | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.559); catalogued as COSV101194651, COSV66944477; called by muse, mutect2, varscan2
- CTR9 | c.958-1G>A p.X320_splice | Splice Site (SNP) | VAF 21/43 reads (49%) | catalogued as COSV100797441; called by muse, mutect2, varscan2
- CWH43 | c.562G>T p.G188W | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as COSV99893836; called by muse, mutect2
- CYP2A13 | c.1463C>T p.T488I | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100386969; called by muse, mutect2, varscan2
- CYP3A4 | c.1399G>A p.G467R (on ENST00000336411; = p.G436R on NM_017460.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs755248651, COSV100315829; called by muse, mutect2, varscan2
- CYP3A5 | c.469G>A p.V157M | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.622); catalogued as COSV56120394; called by muse, mutect2, varscan2
- DARS2 | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs1467038765, COSV53406695; called by muse, mutect2, varscan2
- DDX4 | c.722G>A p.G241E | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as rs1176560132, COSV61758176; called by muse, mutect2, varscan2
- DEFB113 | c.69A>T p.K23N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.424); catalogued as COSV100435438; called by muse, mutect2, varscan2
- DFFB | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV100138768; called by muse, mutect2, varscan2
- DHX15 | c.1721T>G p.M574R | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100391620; called by muse, mutect2, varscan2
- DHX37 | c.1150C>T p.L384F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100439432; called by muse, mutect2
- DLGAP4 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs755772938, COSV100211520; called by muse, mutect2, varscan2
- DMBT1 | c.4954G>A p.E1652K (on ENST00000338354 / NM_001377530.1; = p.E895K on NM_004406.3) | Missense Mutation (SNP) | VAF 38/257 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57540767; called by muse, mutect2, varscan2
- DMTN | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99742050; called by muse, mutect2
- DNAH10 | c.3496C>T p.L1166F (on ENST00000409039; = p.L1105F on NM_207437.3) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.722); catalogued as rs936260566, COSV101292500; called by muse, mutect2, varscan2
- DNAH5 | c.13618C>T p.L4540F | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99452743; called by muse, mutect2, varscan2
- DNAH5 | c.7916G>A p.R2639Q | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs140968268, COSV54202500; called by muse, mutect2, varscan2
- DNAH7 | c.10808C>T p.P3603L | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV56755899; called by muse, mutect2, varscan2
- DNAJB13 | c.430C>T p.L144F | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100334538; called by muse, mutect2, varscan2
- DNM3 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766159947, COSV62458116; called by muse, mutect2, varscan2
- DOK2 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV99374886; called by muse, mutect2, varscan2
- DPYSL5 | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV56513332, COSV99982676; called by muse, mutect2, varscan2
- DSC2 | c.1820C>T p.P607L | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99199776; called by muse, mutect2, varscan2
- DSC3 | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1467268485, COSV100844690; called by muse, mutect2, varscan2
- DSCAM | c.1294G>A p.G432R | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101261234; called by muse, mutect2, varscan2
- DSG3 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs137884016; called by muse, mutect2, varscan2
- DYSF | c.4874C>T p.P1625L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV50640179, COSV99249777; called by muse, mutect2, varscan2
- EBF2 | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV68778085; called by muse, mutect2, varscan2
- EDEM1 | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV99849354; called by muse, mutect2, varscan2
- EFCAB6 | c.2830G>A p.E944K | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.864); catalogued as COSV99414137; called by muse, varscan2
- EHMT1 | c.1211C>T p.T404I | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.296); catalogued as COSV100604124; called by muse, mutect2, varscan2
- EIF2S1 | c.634C>A p.L212I | Missense Mutation (SNP) | VAF 4/73 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99833240; called by muse, mutect2
- ELAVL2 | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs1238539976, COSV99806891; called by muse, mutect2, varscan2
- ELFN2 | c.509C>T p.T170I | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV101297615; called by mutect2, varscan2
- ELMO3 | c.574C>T p.L192= (on ENST00000652269; = p.L139= on NM_024712.5) | Splice Region (SNP) | VAF 30/71 reads (42%) | catalogued as COSV100681848; called by muse, mutect2, varscan2
- EP300 | c.6898C>T p.P2300S | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.063); catalogued as COSV99609495; called by muse, mutect2, varscan2
- EP300 | c.6899C>T p.P2300L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.656); catalogued as rs756496226, COSV99609497; called by muse, mutect2, varscan2
- EPHA1 | c.2122G>A p.G708R | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV99314502; called by muse, mutect2, varscan2
- EPHA1 | c.1042C>T p.L348F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1370189067, COSV99314506; called by muse, mutect2, varscan2
- EPN2 | c.1374T>A p.F458L | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.062); catalogued as COSV100127704; called by muse, mutect2, varscan2
- ERBB4 | c.3898C>T p.P1300S | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); catalogued as rs1325370392, COSV100726753, COSV61535425; called by muse, mutect2
- ERICH1 | c.913G>T p.D305Y | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.347); catalogued as rs778631358, COSV100032845; called by muse, mutect2, varscan2
- ETFBKMT | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.108); catalogued as COSV63189725; called by muse, mutect2, varscan2
- EVPL | c.2278G>A p.D760N | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV101648795; called by mutect2, varscan2
- FAM135B | c.3506G>A p.G1169E | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV52712378; called by muse, mutect2, varscan2
- FAM214A | c.1183C>T p.P395S | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as COSV55922519; called by muse, mutect2, varscan2
- FAM53B | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as rs1365399664, COSV99785016; called by muse, mutect2, varscan2
- FAM83B | c.1628C>T p.S543F | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV100174855, COSV60920969; called by muse, mutect2, varscan2
- FANCM | c.3821A>G p.Y1274C | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV99951488; called by muse, mutect2, varscan2
- FAT2 | c.12748G>A p.D4250N | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99943844; called by muse, mutect2, varscan2
- FBXO15 | c.1330C>T p.P444S | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV99503662; called by muse, mutect2
- FBXO40 | c.1456G>A p.D486N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs989962397, COSV100573269; called by muse, mutect2, varscan2
- FCHO1 | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99406351; called by muse, mutect2, varscan2
- FCRL1 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.965); catalogued as rs772311289, COSV63825465; called by muse, mutect2, varscan2
- FCRL6 | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.85); PolyPhen benign (0.231); catalogued as COSV100220325, COSV58942703; called by muse, varscan2
- FDFT1 | c.1148C>T p.S383F | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.641); catalogued as rs1203733813, COSV99594848; called by muse, mutect2, varscan2
- FLG | c.9473C>T p.S3158F | Missense Mutation (SNP) | VAF 40/369 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV64250027; called by muse, mutect2, varscan2
- FMNL3 | c.1396C>T p.Q466* | Nonsense Mutation (SNP) | VAF 3/22 reads (14%) | catalogued as rs1357643655, COSV99526829; called by muse, mutect2
- FMO2 | c.809G>A p.G270D | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99269290; called by muse, mutect2, varscan2
- FMOD | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100724605; called by muse, mutect2, varscan2
- FOXP4 | c.820C>T p.H274Y (on ENST00000307972 / NM_001012426.1; = p.H273Y on NM_138457.3) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as COSV100332932; called by muse, mutect2, varscan2
- FRMPD1 | c.47G>A p.R16K | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV100733619, COSV63382998; called by muse, mutect2
- FRMPD3 | c.4411C>T p.P1471S | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV99346863; called by muse, mutect2, varscan2
- FSIP2 | c.15953C>T p.S5318F | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV100555983; called by muse, mutect2, varscan2
- FSIP2 | c.16975G>A p.D5659N | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV100555986; called by muse, mutect2, varscan2
- FSTL5 | c.1832C>T p.T611I | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as rs1261701952, COSV100059626; called by muse, mutect2, varscan2
- FUT3 | c.187C>T p.L63F | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as COSV99744857; called by muse, mutect2, varscan2
- FUT9 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.303); catalogued as COSV100134105; called by muse, mutect2
- FYN | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV99992305; called by muse, mutect2, varscan2
- GABRQ | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as rs1556820516, COSV100941404, COSV64783731; called by muse, mutect2, varscan2
- GBP7 | c.1358G>A p.G453E | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99643371; called by muse, mutect2
- GBP7 | c.590A>T p.D197V | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99643375; called by muse, mutect2, varscan2
- GCKR | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); catalogued as COSV53107229; called by muse, mutect2
- GGT5 | c.1367G>A p.G456E | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.239); catalogued as COSV99571790; called by muse, mutect2, varscan2
- GIMAP2 | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.233); catalogued as COSV99785483; called by muse, mutect2, varscan2
- GJA5 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.08); catalogued as rs782422906, COSV99605758; called by muse, mutect2, varscan2
- GJB2 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV101241508; called by muse, mutect2, varscan2
- GJC2 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as COSV100812986; called by muse, mutect2
- GNGT2 | c.39G>A p.M13I | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV99865761; called by muse, mutect2, varscan2
- GOLGB1 | c.4472C>T p.S1491F | Missense Mutation (SNP) | VAF 32/239 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61471261; called by muse, mutect2, varscan2
- GPR119 | c.862C>A p.L288M | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV99358699; called by muse, mutect2, varscan2
- GPR151 | c.198G>A p.W66* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as COSV99694365; called by muse, mutect2, varscan2
- GPRASP1 | c.3623C>T p.P1208L | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64355208; called by muse, mutect2, varscan2
- GPRC6A | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as COSV59952733; called by muse, mutect2, varscan2
- GRIN2A | c.2884G>A p.E962K | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.338); catalogued as rs765370528, COSV58022947, COSV58048177; called by muse, mutect2, varscan2
- GRK4 | c.784T>G p.L262V (on ENST00000398052 / NM_182982.3; = p.L230V on NM_005307.3) | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs761549972, COSV100584230; called by muse, mutect2, varscan2
- GTF3C3 | c.1762C>T p.L588F | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.333); catalogued as rs1407489340, COSV55832163, COSV99826919; called by muse, mutect2, varscan2
- GYG1 | c.885T>A p.D295E | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV99936926; called by muse, mutect2, varscan2
- GZMK | c.106C>T p.H36Y | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as COSV99140966; called by muse, mutect2, varscan2
- HAUS4 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs1473313395, COSV52826942; called by muse, mutect2, varscan2
- HCN1 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV100301650; called by muse, mutect2, varscan2
- HIVEP3 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV99913614; called by muse, mutect2, varscan2
- HIVEP3 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99913615; called by muse, mutect2, varscan2
- HMCN1 | c.8139G>A p.Q2713= | Splice Region (SNP) | VAF 12/70 reads (17%) | catalogued as COSV54940855, COSV99634005; called by muse, mutect2, varscan2
- HMCN1 | c.11573C>T p.S3858L | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99634008; called by muse, mutect2, varscan2
- HROB | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 98/237 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs147596694, COSV55369413; called by muse, mutect2, varscan2
- HS3ST4 | c.729G>A p.W243* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as rs1322707027, COSV100502484; called by muse, mutect2
- HSPG2 | c.1237C>T p.R413W | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs745376918, COSV65930158; called by muse, mutect2, varscan2
- HYAL4 | c.1376C>T p.S459F | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99772406; called by muse, mutect2, varscan2
- IDO1 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs370075063, COSV99503510; called by muse, mutect2, varscan2
- IFNW1 | c.34G>A p.V12M | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV101207635; called by muse, mutect2, varscan2
- IFT122 | c.2794C>T p.P932S (on ENST00000348417 / NM_052989.3; = p.P873S on NM_018262.4) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV99959701; called by muse, mutect2, varscan2
- IFT140 | c.2381C>T p.S794F | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54151631; called by muse, mutect2, varscan2
- IGLV7-43 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.796); catalogued as rs778081995; called by muse, mutect2, varscan2
- IGSF1 | c.3571G>A p.E1191K | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.987); catalogued as COSV63837234; called by muse, mutect2, varscan2
- IGSF3 | c.1327C>T p.R443C (on ENST00000369486 / NM_001007237.3; = p.R463C on NM_001542.4) | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs777898801, COSV59590880; called by muse, mutect2, varscan2
- IL12A | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99975844; called by muse, mutect2, varscan2
- IL20RA | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100360179; called by muse, mutect2, varscan2
- IMPG1 | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375185954; called by muse, mutect2, varscan2
- INPP5J | c.1136G>A p.G379E | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs1272656883, COSV100459700; called by muse, mutect2
- IPP | c.493C>T p.H165Y | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as rs775758891, COSV100739677; called by muse, mutect2, varscan2
- IQCB1 | c.445C>T p.L149F | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV60439936; called by muse, mutect2, varscan2
- ITGAX | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as COSV99191957; called by muse, mutect2
- ITK | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101439852, COSV70065503; called by muse, mutect2, varscan2
- KCNB1 | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.814); catalogued as rs755481445, COSV100870504; called by muse, mutect2, varscan2
- KCNC4 | c.1831C>T p.L611F | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.084); catalogued as COSV100873674; called by muse, mutect2, varscan2
- KCNH4 | c.2602G>A p.E868K | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.6); PolyPhen benign (0.037); catalogued as COSV52919827, COSV99237752; called by muse, mutect2, varscan2
- KCNIP4 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs866834620, COSV62850327; called by muse, mutect2, varscan2
- KCNMA1 | c.1199C>T p.S400F | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.502); catalogued as COSV99699078; called by muse, mutect2, varscan2
- KCNV1 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.364); catalogued as rs868751450, COSV52087092, COSV52088724; called by muse, mutect2, varscan2
- KDM3A | c.3407C>T p.P1136L | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100460832; called by muse, mutect2, varscan2
- KDM3B | c.3500C>T p.P1167L | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs528636129, COSV100070088; called by muse, mutect2, varscan2
- KIAA0319 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as COSV100985744; called by muse, mutect2, varscan2
- KLF6 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773677946, COSV51494175, COSV99434932; called by mutect2, varscan2
- KLHL13 | c.483G>A p.M161I | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as COSV53244984, COSV53249868, COSV99035215; called by muse, mutect2, varscan2
- KLHL41 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.057); catalogued as COSV99500555; called by muse, mutect2, varscan2
- KNOP1 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99575316; called by muse, mutect2, varscan2
- KNSTRN | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.037); catalogued as COSV99991973, COSV99992040; called by muse, mutect2
- KNTC1 | c.3653C>T p.S1218L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV61083717; called by muse, mutect2, varscan2
- KRAS | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as COSV55511879; called by muse, mutect2
- KRT3 | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.982); catalogued as COSV58817568; called by muse, mutect2
- KRTAP5-3 | c.4G>A p.G2S | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as COSV101294520; called by muse, mutect2, varscan2
- LAMA4 | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs1452226611, COSV100039131, COSV57905025; called by muse, mutect2, varscan2
- LAMA5 | c.761C>T p.T254I | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1446006926, COSV99441662; called by muse, mutect2, varscan2
- LAMB2 | c.2032C>T p.P678S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs780137635, COSV59736436; called by muse, mutect2, varscan2
- LBR | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 52/100 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55292778; called by muse, mutect2, varscan2
- LHCGR | c.1547C>T p.P516L | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99683632; called by muse, mutect2, varscan2
- LIG1 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.239); catalogued as rs185089911, COSV54396413; called by muse, mutect2, varscan2
- LIPI | c.604+1G>A p.X202_splice | Splice Site (SNP) | VAF 28/61 reads (46%) | catalogued as COSV100753925, COSV60709073; called by muse, mutect2, varscan2
- LMBR1 | c.1262G>A p.R421K | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.814); catalogued as COSV100626786; called by muse, mutect2, varscan2
- LPA | c.4501G>A p.D1501N | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs1347158720, COSV100307750; called by muse, mutect2, varscan2
- LPIN1 | c.1673G>A p.R558K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV56768233, COSV99878040; called by muse, mutect2, varscan2
- LRAT | c.107G>T p.R36M | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as COSV100312175; called by muse, mutect2, varscan2
- LRG1 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.826); catalogued as rs765306791, COSV56705348; called by muse, mutect2, varscan2
- LRG1 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as COSV100015063; called by muse, mutect2, varscan2
- LRP4 | c.1928C>T p.P643L | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101066800; called by muse, mutect2, varscan2
- LRRC37B | c.2242C>T p.P748S | Missense Mutation (SNP) | VAF 68/206 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs752408763, COSV58955435; called by muse, mutect2, varscan2
- LRRN3 | c.669C>A p.N223K | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); catalogued as COSV100072604; called by muse, mutect2, varscan2
- LTF | c.861G>A p.W287* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99210660; called by muse, mutect2, varscan2
- LTN1 | c.3491G>A p.G1164D | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.157); catalogued as COSV100798128; called by muse, mutect2, varscan2
- LTN1 | c.3490G>A p.G1164S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV100798129; called by muse, mutect2, varscan2
- LUZP2 | c.609G>A p.M203I | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV61204672; called by muse, mutect2, varscan2
- LY6G6F | c.857T>A p.L286* | Nonsense Mutation (SNP) | VAF 26/148 reads (18%) | catalogued as COSV101011719; called by muse, mutect2, varscan2
- MAEL | c.1247C>T p.S416L | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.014); catalogued as COSV63306344; called by muse, mutect2, varscan2
- MALT1 | c.2303C>T p.P768L | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); catalogued as COSV100618830; called by muse, mutect2, varscan2
- MAMDC2 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.271); catalogued as COSV101015721; called by muse, mutect2, varscan2
- MAN1A1 | c.1153A>G p.K385E | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100870570, COSV100870724; called by muse, mutect2, varscan2
- MAN1C1 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99848812; called by muse, mutect2, varscan2
- MAP1B | c.5279C>T p.S1760F | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as rs1359950394, COSV99702813; called by muse, mutect2, varscan2
- MAP1B | c.6535G>A p.D2179N | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1335834052, COSV99702814; called by muse, mutect2, varscan2
- MAP3K15 | c.2030G>A p.R677Q | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as COSV58841640; called by muse, mutect2, varscan2
- MAP3K21 | c.2140C>T p.P714S | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as rs1322245837, COSV100786137; called by muse, mutect2, varscan2
- MAPK8IP3 | c.2750G>A p.G917E | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.941); catalogued as COSV99169560; called by muse, mutect2, varscan2
- MAST2 | c.2446C>T p.R816C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as rs746251392, COSV100788425, COSV63618275; called by muse, varscan2
- MATN3 | c.1156A>T p.K386* | Nonsense Mutation (SNP) | VAF 7/50 reads (14%) | catalogued as COSV101337467; called by muse, mutect2, varscan2
- MATN3 | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as rs763284676, COSV101337469; called by muse, mutect2
- MCF2L | c.2926C>G p.P976A (on ENST00000375608; = p.P944A on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.692); catalogued as COSV99996062; called by muse, mutect2, varscan2
- MCF2L | c.2927C>T p.P976L (on ENST00000375608; = p.P944L on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as rs1280835995, COSV99996069; called by muse, mutect2, varscan2
- MCF2L2 | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as rs994786366, COSV100193587; called by muse, mutect2, varscan2
- MCTP2 | c.998C>A p.A333D | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as rs769348862, COSV100537640; called by muse, mutect2, varscan2
- MDM2 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.058); catalogued as COSV99254687; called by muse, mutect2, varscan2
- MED12 | c.952C>T p.H318Y | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV100379415, COSV61356365; called by muse, mutect2, varscan2
- MED25 | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100457835; called by muse, mutect2, varscan2
- MEI1 | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs913004878, COSV55904904; called by muse, mutect2, varscan2
- MEIS2 | c.559C>T p.L187F (on ENST00000561208 / NM_170675.5; = p.L174F on NM_002399.3) | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as COSV99577054; called by muse, mutect2, varscan2
- MERTK | c.1769G>A p.G590E | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99775123; called by muse, mutect2, varscan2
- METTL16 | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.147); catalogued as COSV54011945; called by muse, mutect2, varscan2
- METTL2A | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs777410698, COSV100274285; called by muse, mutect2, varscan2
- MLC1 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.647); catalogued as rs1339531790, COSV100286502; called by muse, mutect2, varscan2
- MLST8 | c.454A>T p.I152F | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV100063890; called by muse, mutect2, varscan2
- MLXIPL | c.1031C>T p.S344F | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as COSV100515233; called by muse, mutect2, varscan2
- MMP28 | c.752C>T p.S251L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs564376727; called by muse, mutect2
- MOG | c.94T>C p.F32L | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100973089; called by muse, mutect2, varscan2
- MRGPRX2 | c.611C>G p.A204G | Missense Mutation (SNP) | VAF 2/16 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100316812, COSV61674336; called by muse, mutect2
- MROH2B | c.1647G>A p.W549* | Nonsense Mutation (SNP) | VAF 19/79 reads (24%) | catalogued as COSV68182214, COSV68190008; called by muse, mutect2, varscan2
- MROH5 | c.64G>A p.V22M | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.01); catalogued as rs371943569; called by muse, mutect2, varscan2
- MROH8 | c.1312G>T p.E438* | Nonsense Mutation (SNP) | VAF 65/241 reads (27%) | catalogued as COSV99457769; called by muse, mutect2, varscan2
- MRPL4 | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV99460208; called by muse, mutect2, varscan2
- MUC16 | c.33118G>A p.G11040R | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.157); catalogued as COSV67501983; called by muse, mutect2, varscan2
- MUC16 | c.6514G>A p.A2172T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.483); catalogued as rs1222502710, COSV67492381; called by muse, mutect2, varscan2
- MXRA5 | c.8146G>A p.E2716K | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs1206337351, COSV99478608; called by muse, mutect2, varscan2
- MYH10 | c.5735A>G p.E1912G | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV99346036; called by muse, mutect2, varscan2
- MYH14 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1218671199, COSV99222676; called by muse, mutect2
- MYL7 | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV56267337; called by muse, mutect2, varscan2
- MYO1B | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.133); catalogued as COSV100269793; called by muse, mutect2, varscan2
- MYO3A | c.4189C>T p.P1397S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV56331360; called by muse, mutect2, varscan2
- MYO3B | c.2198C>T p.S733L | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866879141, COSV100509399, COSV58714099; called by muse, mutect2, varscan2
- MYOCD | c.1766G>A p.R589K | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.93); PolyPhen benign (0.041); catalogued as COSV100590092, COSV100591210, COSV58496552; called by muse, mutect2, varscan2
- MYOCD | c.2027C>T p.S676L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.173); catalogued as rs749557798, COSV58514840; called by muse, mutect2, varscan2
- MYOM1 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.932); catalogued as COSV99867928; called by muse, mutect2, varscan2
- NAA30 | c.981G>T p.K327N | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV100035987; called by muse, mutect2
- NAA80 | c.826G>A p.G276R (on ENST00000417393 / NM_001200018.2; = p.G298R on NM_012191.4) | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as COSV56499369, COSV99807836; called by muse, mutect2, varscan2
- NANOG | c.845G>A p.R282K | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99981747; called by mutect2, varscan2
- NCBP2L | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.184); catalogued as rs1387016752, COSV100966519; called by muse, mutect2, varscan2
- NCOA2 | c.1331C>T p.S444F | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.476); catalogued as COSV101476044; called by muse, mutect2, varscan2
- NECAB3 | c.1070+1G>A p.X357_splice (on ENST00000246190 / NM_031232.4; = p.X323_splice on NM_031231.4) | Splice Site (SNP) | VAF 30/212 reads (14%) | catalogued as COSV99865061; called by muse, varscan2
- NECAB3 | c.1070G>A p.R357K (on ENST00000246190 / NM_031232.4; = p.R323K on NM_031231.4) | Missense Mutation (SNP) | VAF 31/216 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.626); catalogued as COSV99865063; called by muse, varscan2
- NF1 | c.2143G>T p.E715* | Nonsense Mutation (SNP) | VAF 13/93 reads (14%) | catalogued as rs1336584572, COSV100647957; called by muse, mutect2, varscan2
- NF1 | c.4372G>A p.E1458K (on ENST00000358273 / NM_001042492.3; = p.E1437K on NM_000267.3) | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as rs1135402858, CM1111777, COSV100647958, COSV62197003; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NID1 | c.2881G>A p.G961R | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as rs773735935, COSV99938081; called by muse, mutect2, varscan2
- NID2 | c.2738C>T p.S913F | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99357074; called by muse, mutect2, varscan2
- NID2 | c.1552G>A p.G518R | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1353733078, COSV99357076; called by muse, mutect2, varscan2
- NLGN4Y | c.1250G>A p.R417Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.868); catalogued as COSV100197033; called by muse, mutect2, varscan2
- NLRC3 | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100073229; called by muse, mutect2
- NLRC5 | c.1906C>T p.P636S | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.082); catalogued as COSV99347992; called by muse, mutect2, varscan2
- NLRP5 | c.409A>G p.T137A | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.94); PolyPhen benign (0.009); catalogued as rs1353425760, COSV101173834; called by muse, mutect2, varscan2
- NLRP9 | c.72G>A p.W24* | Nonsense Mutation (SNP) | VAF 20/149 reads (13%) | catalogued as COSV100243316; called by muse, mutect2, varscan2
- NMNAT2 | c.175G>A p.G59S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.595); catalogued as COSV99680278; called by muse, mutect2, varscan2
- NOD2 | c.2930A>T p.E977V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV100318799; called by muse, mutect2, varscan2
- NOSTRIN | c.547G>A p.E183K (on ENST00000317647 / NM_001039724.4; = p.E105K on NM_052946.3) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.526); catalogued as COSV100473908; called by muse, mutect2, varscan2
- NOSTRIN | c.856G>A p.E286K (on ENST00000317647 / NM_001039724.4; = p.E208K on NM_052946.3) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as COSV58320708; called by muse, mutect2, varscan2
- NOTUM | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.125); catalogued as COSV101293820; called by muse, varscan2
- NOVA1 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1375881995, COSV99948435; called by muse, mutect2, varscan2
- NPEPPS | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as rs763445892, COSV100443908; called by muse, mutect2
- NPTX1 | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as COSV100151144; called by muse, mutect2, varscan2
- NR4A1 | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV54485720; called by muse, mutect2, varscan2
- NR4A1 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.065); catalogued as COSV99671615; called by muse, mutect2, varscan2
- NRXN3 | c.2584C>T p.R862C (on ENST00000335750 / NM_001330195.2; = p.R489C on NM_004796.6) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1275495927, COSV100203243; called by muse, mutect2, varscan2
- NTSR2 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.102); catalogued as rs1359024058, COSV100183997; called by muse, mutect2, varscan2
- NUP58 | c.1666A>G p.S556G | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.979); catalogued as COSV101098874; called by muse, mutect2, varscan2
- NUTM1 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.97); PolyPhen benign (0.037); catalogued as COSV100412509; called by muse, mutect2, varscan2
- NYNRIN | c.3626C>T p.P1209L | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.018); catalogued as rs1022604616, COSV101230666; called by muse, mutect2, varscan2
- OBSCN | c.10021G>A p.E3341K | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.727); catalogued as COSV99482739; called by muse, mutect2, varscan2
- OLAH | c.205G>A p.E69K (on ENST00000378228 / NM_001039702.3; = p.E122K on NM_018324.3) | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100984839, COSV65494259; called by muse, mutect2, varscan2
- OLFML2A | c.1726G>A p.G576R | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770069153, COSV99992523, COSV99992806; called by muse, mutect2, varscan2
- OLFML2A | c.1727G>A p.G576E | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1370818088, COSV99992809; called by muse, mutect2, varscan2
- OPRL1 | c.887C>T p.T296I | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV100402226; called by muse, mutect2, varscan2
- OR11H12 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs1370242111, COSV73569293; called by muse, varscan2
- OR1B1 | c.769C>T p.L257F | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs994048993, COSV100506521; called by muse, mutect2, varscan2
- OR1K1 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52957047; called by muse, mutect2
- OR1N1 | c.592T>A p.F198I | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.17); catalogued as COSV100509808; called by muse, mutect2, varscan2
- OR2A2 | c.266G>A p.R89K | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs139387901, COSV68872305; called by muse, mutect2, varscan2
- OR2AK2 | c.386C>G p.P129R | Missense Mutation (SNP) | VAF 8/212 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100824256; called by muse, mutect2
- OR2C3 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs553883831, COSV100825763; called by muse, mutect2, varscan2
- OR2M4 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as rs766100706, COSV60708950; called by muse, mutect2, varscan2
- OR2T1 | c.941C>A p.S314* | Nonsense Mutation (SNP) | VAF 55/125 reads (44%) | catalogued as rs1340394269, COSV100822345; called by muse, mutect2, varscan2
- OR2W1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs1226192074, COSV65851432, COSV65851562, COSV65852021; called by muse, mutect2, varscan2
- OR4K17 | c.383A>G p.K128R | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.253); catalogued as COSV59648638; called by muse, mutect2, varscan2
- OR51A4 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.232); catalogued as rs267602929, COSV66749060; called by muse, mutect2, varscan2
- OR51I1 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV66508459; called by muse, mutect2, varscan2
- OR52A1 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs866627196, COSV100200553, COSV61093227; called by muse, mutect2, varscan2
- OR5H14 | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101454248; called by muse, mutect2, varscan2
- OR5H14 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV71193708; called by muse, mutect2
- OR5K4 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs267599956, COSV100721385; called by muse, mutect2, varscan2
- OR6F1 | c.919G>A p.G307R | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV57469171; called by muse, mutect2, varscan2
- OR6V1 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs760856656, COSV69236835; called by muse, mutect2, varscan2
- OR8H3 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV100539118; called by muse, mutect2, varscan2
- OSBP2 | c.359C>T p.T120I | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV100213567; called by muse, mutect2, varscan2
- OSBPL1A | c.1178T>G p.M393R | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as COSV100112475; called by muse, mutect2, varscan2
- OTOGL | c.4723G>A p.E1575K (on ENST00000547103; = p.E1566K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.691); catalogued as rs577690596, COSV54014641; called by muse, mutect2, varscan2
- OVGP1 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100868257, COSV63859182; called by muse, mutect2
- PAPPA | c.2120G>A p.G707E | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100075006; called by muse, mutect2, varscan2
- PASK | c.2987C>T p.S996F | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV99300056; called by muse, mutect2, varscan2
- PAX7 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs760954795, COSV100946938, COSV64751900; called by muse, mutect2, varscan2
- PCDH10 | c.1030G>A p.V344M | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99994277; called by muse, mutect2, varscan2
- PCDH15 | c.4567G>A p.E1523K (on ENST00000644397 / NM_001354429.2; = p.E1472K on NM_001142769.3) | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.717); catalogued as rs1403940488, COSV64685933, COSV64690210; called by muse, mutect2, varscan2
- PCDHA7 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 44/187 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.982); catalogued as COSV65343559; called by muse, mutect2, varscan2
- PCED1B | c.7C>T p.L3F | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.345); catalogued as rs1183340924, COSV101423682; called by muse, mutect2, varscan2
- PCNX2 | c.4085G>A p.R1362Q | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs370569341; called by muse, varscan2
- PDS5B | c.1787C>T p.P596L | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (1); PolyPhen possibly damaging (0.818); catalogued as COSV100221390; called by muse, mutect2, varscan2
- PDZD2 | c.7833A>T p.K2611N | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.379); catalogued as COSV99226215; called by muse, mutect2, varscan2
- PGBD1 | c.1466T>C p.V489A | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV99460753; called by muse, mutect2, varscan2
- PHIP | c.4682C>T p.P1561L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.351); catalogued as COSV51501726; called by muse, mutect2, varscan2
- PHLPP2 | c.3919C>T p.P1307S | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV100673795; called by muse, mutect2, varscan2
- PHOX2B | c.913A>T p.K305* | Nonsense Mutation (SNP) | VAF 3/9 reads (33%) | catalogued as COSV99891614; called by muse, mutect2
- PIWIL2 | c.1538C>T p.A513V | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.03); catalogued as COSV100769509; called by muse, mutect2, varscan2
- PKLR | c.1575G>A p.W525* | Nonsense Mutation (SNP) | VAF 58/120 reads (48%) | catalogued as COSV100712993; called by muse, mutect2, varscan2
- PLCB1 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV62066702; called by muse, mutect2, varscan2
- PLCE1 | c.905A>T p.D302V | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.143); catalogued as COSV99596580; called by muse, mutect2, varscan2
- PLCG2 | c.2612C>T p.S871F | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.218); catalogued as rs1159159204, COSV63869609; called by muse, mutect2, varscan2
- PLCH2 | c.3701G>A p.R1234Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.616); catalogued as rs781343610, COSV53945456; called by muse, mutect2, varscan2
- PLEKHG4B | c.616C>T p.P206S (on ENST00000283426; = p.P562S on NM_052909.5) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs754101456, COSV99360885; called by muse, mutect2, varscan2
- PLEKHH1 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV100233412; called by muse, mutect2, varscan2
- PLG | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.345); catalogued as COSV51980836; called by muse, mutect2
- PLIN5 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs369901049; called by muse, mutect2, varscan2
- PLK1 | c.884C>T p.T295I | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.199); catalogued as rs1274670002, COSV100267418; called by muse, mutect2, varscan2
- PNPLA7 | c.3865G>A p.D1289N | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV99481231; called by muse, mutect2, varscan2
- POLB | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as COSV55182524; called by muse, mutect2, varscan2
- POLN | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV67024146; called by muse, mutect2, varscan2
- PON1 | c.969A>T p.E323D | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99196966; called by muse, mutect2, varscan2
- POSTN | c.2272C>T p.P758S | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.96); catalogued as rs1323620663, COSV101123454; called by muse, mutect2, varscan2
- PPEF2 | c.812T>C p.L271P | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99714856; called by muse, mutect2, varscan2
- PPP2R1A | c.421T>C p.F141L | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV100436415; called by muse, mutect2, varscan2
- PPP2R2A | c.366G>A p.W122* | Nonsense Mutation (SNP) | VAF 15/75 reads (20%) | catalogued as rs1312017222, COSV60096727; called by muse, mutect2, varscan2
- PRAMEF1 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 19/257 reads (7%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.962); catalogued as COSV60007293; called by muse, mutect2
- PRB4 | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.017); catalogued as rs562508140, COSV54398513; called by muse, varscan2
- PRRG3 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs781279979, COSV64851056; called by muse, mutect2, varscan2
- PSG4 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as rs769047324, COSV54938968, COSV99737771; called by muse, mutect2, varscan2
- PSTK | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV100924756; called by muse, varscan2
- PTPA | c.779C>T p.S260L (on ENST00000337738 / NM_178001.2; = p.S225L on NM_021131.5) | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV61234704; called by muse, mutect2, varscan2
- PTPRA | c.2077C>T p.H693Y | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99400454; called by muse, mutect2, varscan2
- PTPRC | c.1315A>G p.K439E | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as COSV100722983; called by muse, mutect2, varscan2
- PTPRU | c.2747G>A p.G916D | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV100113510; called by muse, mutect2, varscan2
- PUM1 | c.2422A>T p.S808C | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV99928748; called by muse, mutect2, varscan2
- R3HDM2 | c.2837C>T p.S946F | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.741); catalogued as COSV100234694; called by muse, mutect2, varscan2
- RAB11FIP4 | c.1787C>T p.S596L | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs778767376, COSV57930340; called by muse, mutect2, varscan2
- RAB34 | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs1479942630, COSV99973006; called by muse, mutect2, varscan2
- RAG2 | c.515G>A p.W172* | Nonsense Mutation (SNP) | VAF 29/61 reads (48%) | catalogued as COSV100271446; called by muse, mutect2, varscan2
- RC3H1 | c.3276G>C p.L1092F | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.193); catalogued as COSV99281666; called by muse, mutect2
- REG1B | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as rs534911034, COSV100521481; called by muse, mutect2, varscan2
- REV3L | c.1799C>T p.S600L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as rs1309555424, COSV100725575; called by muse, mutect2, varscan2
- RFESD | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs764934254, COSV99174175; called by muse, mutect2, varscan2
- RFPL3 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV99967232; called by muse, mutect2
- RFX7 | c.323C>T p.A108V (on ENST00000559447 / NM_001368074.1; = p.A205V on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs769558133, COSV57965124; called by muse, mutect2, varscan2
- RGP1 | c.569A>C p.K190T | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as COSV100960324; called by muse, mutect2, varscan2
- RGS22 | c.1106T>C p.L369S | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV100693656; called by muse, mutect2, varscan2
- RHBDF2 | c.881T>A p.F294Y | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100489603; called by muse, mutect2
- RIPPLY3 | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs770895515, COSV100289281, COSV100289410; called by mutect2, varscan2
- RNASEH2A | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.106); catalogued as rs1474678539, COSV55551090; called by muse, mutect2, varscan2
- RND1 | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.995); catalogued as COSV59045125; called by muse, mutect2, varscan2
- RNF168 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100535087; called by muse, mutect2, varscan2
- ROBO1 | c.4151C>T p.S1384F | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV101459145; called by muse, mutect2, varscan2
- RP1L1 | c.6110T>C p.V2037A | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as rs1369962805, COSV101223513; called by muse, mutect2, varscan2
- RTN4IP1 | c.977C>T p.S326L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.299); catalogued as COSV100954220; called by muse, mutect2, varscan2
- RUNDC3B | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.917); catalogued as rs756808827, COSV55945690; called by muse, mutect2, varscan2
- RYR2 | c.1510C>T p.R504C | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs373502556, COSV63704372, COSV99053513; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAMD9 | c.3548C>T p.P1183L | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1480540811, COSV101180303; called by muse, mutect2, varscan2
- SBSN | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV101510099; called by muse, mutect2, varscan2
- SCAF4 | c.3365C>T p.S1122F | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.084); catalogued as COSV99532245; called by muse, mutect2, varscan2
- SCAPER | c.2809G>A p.G937R | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV100239206; called by muse, mutect2
- SCARA5 | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.259); catalogued as rs199844106, COSV100108035; called by muse, mutect2, varscan2
- SDR16C5 | c.341A>G p.K114R | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.042); catalogued as COSV100374109; called by mutect2, varscan2
- SEC24C | c.1384C>T p.Q462* | Nonsense Mutation (SNP) | VAF 18/100 reads (18%) | catalogued as COSV100227098; called by muse, mutect2, varscan2
- SELENON | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62526674; called by muse, mutect2, varscan2
- SEMA3A | c.181C>T p.L61F | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.532); catalogued as COSV99547683; called by muse, mutect2, varscan2
- SEMA3D | c.1028G>A p.G343E | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99407197; called by muse, mutect2, varscan2
- SERPINA4 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.073); catalogued as COSV54068902; called by muse, mutect2, varscan2
- SERPINB4 | c.379T>A p.Y127N | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100345917; called by muse, mutect2, varscan2
- SERPING1 | c.676C>T p.H226Y | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as COSV99558114; called by muse, mutect2, varscan2
- SERTAD2 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as rs1261010235, COSV100512257; called by muse, mutect2, varscan2
- SERTAD2 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV57641311; called by muse, mutect2, varscan2
- SETX | c.1433T>G p.L478R | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99810609; called by muse, mutect2, varscan2
- SEZ6L2 | c.2170C>T p.P724S (on ENST00000308713 / NM_001114099.3; = p.P654S on NM_012410.4) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.056); catalogued as COSV100435725; called by muse, mutect2, varscan2
- SFTPB | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.377); catalogued as rs1248137913, COSV100667277; called by muse, mutect2, varscan2
- SHISA2 | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100096563; called by muse, mutect2, varscan2
- SHROOM3 | c.2276G>A p.R759K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs770482470, COSV99935053; called by muse, mutect2, varscan2
- SHROOM4 | c.3624T>A p.F1208L | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV99174215; called by muse, mutect2, varscan2
- SI | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200745562, COSV52269530; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SIM1 | c.1145C>T p.S382F | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.463); catalogued as rs774273867, COSV53489015, COSV99492653; called by muse, mutect2, varscan2
- SLAMF9 | c.325C>T p.Q109* | Nonsense Mutation (SNP) | VAF 23/86 reads (27%) | catalogued as COSV100928176; called by muse, mutect2, varscan2
- SLC13A5 | c.1064C>T p.S355F | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99546116; called by muse, mutect2
- SLC22A10 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.313); catalogued as rs867883268, COSV100235953; called by muse, mutect2, varscan2
- SLC22A15 | c.473T>A p.F158Y | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as rs780197058, COSV101047359; called by mutect2, varscan2
- SLC24A3 | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs545035420, COSV100042544; called by mutect2, varscan2
- SLC25A42 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1293888469, COSV59380313; called by muse, mutect2
- SLC26A3 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776026508, COSV60641544; called by muse, mutect2, varscan2
- SLC27A4 | c.1097C>T p.S366F | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as COSV100307436; called by muse, mutect2, varscan2
- SLC2A13 | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370937258; called by muse, mutect2, varscan2
- SLC47A2 | c.628C>T p.H210Y | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.013); catalogued as COSV100328201; called by muse, mutect2, varscan2
- SLC6A7 | c.1625T>C p.M542T | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.497); catalogued as COSV100046486; called by muse, mutect2, varscan2
- SLC9C2 | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as rs1277971580, COSV62945459; called by muse, mutect2, varscan2
- SLC9C2 | c.73C>T p.L25F | Missense Mutation (SNP) | VAF 43/197 reads (22%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.001); catalogued as COSV100876946; called by muse, mutect2, varscan2
- SLCO2A1 | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100189233; called by muse, mutect2, varscan2
- SLCO3A1 | c.1999G>C p.E667Q | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as rs1301736744, COSV100575806; called by muse, mutect2, varscan2
- SLFN11 | c.942G>A p.M314I | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV100390905; called by muse, mutect2
- SLITRK4 | c.2182G>A p.E728K | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV100567458; called by muse, mutect2, varscan2
- SLX4 | c.2449G>A p.E817K | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV53563059; called by muse, mutect2, varscan2
- SMARCA2 | c.492G>A p.M164I | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.186); catalogued as COSV100571443; called by muse, mutect2, varscan2
- SNAI1 | c.188C>T p.S63F | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV54864667, COSV99723992; called by muse, mutect2, varscan2
- SNCAIP | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1395246796, COSV99747599; called by muse, mutect2, varscan2
- SNCAIP | c.2219C>T p.S740F | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV99749830; called by muse, mutect2, varscan2
- SNCAIP | c.2482C>T p.P828S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV54401745; called by muse, mutect2, varscan2
- SORBS2 | c.1508G>A p.R503Q | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as rs774908326, COSV53009752; called by muse, mutect2, varscan2
- SOS2 | c.1888C>T p.R630C | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1394217728, COSV53564218; called by muse, mutect2, varscan2
- SPATA31D1 | c.598C>T p.L200F | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.204); catalogued as rs1290049382, COSV100782991, COSV61201755; called by muse, mutect2, varscan2
- SPDL1 | c.1252C>T p.Q418* | Nonsense Mutation (SNP) | VAF 14/80 reads (18%) | catalogued as rs1365865754, COSV99517690; called by muse, mutect2, varscan2
- SPEG | c.8822C>T p.S2941F | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV100405345; called by muse, mutect2
- SPIRE2 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1296868495, COSV100988950; called by muse, mutect2, varscan2
- SPTA1 | c.7138C>T p.L2380F | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100778957, COSV100779064; called by muse, mutect2, varscan2
- SPTBN4 | c.4072G>A p.E1358K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV100151779; called by muse, mutect2
- SRRM2 | c.6698C>T p.P2233L | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV99241665; called by muse, mutect2
- ST18 | c.2812G>A p.E938K | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99390715; called by muse, mutect2, varscan2
- ST8SIA3 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 4/21 reads (19%) | PolyPhen possibly damaging (0.885); catalogued as rs778352785, COSV100129729, COSV60655559; called by muse, mutect2, varscan2
- STARD8 | c.1996C>T p.Q666* | Nonsense Mutation (SNP) | VAF 11/19 reads (58%) | catalogued as COSV99367393; called by muse, mutect2, varscan2
- STAT2 | c.2380G>T p.D794Y | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99950716; called by muse, mutect2, varscan2
- STC1 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as COSV99282686; called by muse, mutect2, varscan2
- SYCP2L | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 10/86 reads (12%) | catalogued as COSV51654945; called by muse, mutect2, varscan2
- SYNE1 | c.7258G>A p.E2420K (on ENST00000367255 / NM_182961.4; = p.E2427K on NM_033071.3) | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.055); catalogued as COSV55062004, COSV99574928; called by muse, mutect2, varscan2
- TAF2 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs932501620, COSV100558393; called by muse, mutect2
- TAP2 | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs771425114, COSV100886938; called by muse, mutect2, varscan2
- TARBP1 | c.2347T>A p.L783M | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99241971; called by muse, mutect2
- TBL3 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as COSV100225030; called by muse, mutect2, varscan2
- TCHHL1 | c.1834C>T p.P612S | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100916581; called by muse, mutect2, varscan2
- TENM1 | c.4496C>T p.S1499F | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100950568, COSV100950804; called by muse, mutect2, varscan2
- TENM2 | c.3031A>G p.T1011A (on ENST00000518659 / NM_001122679.2; = p.T779A on NM_001080428.3) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.392); catalogued as rs751050478, COSV101319352; called by muse, mutect2, varscan2
- TENM4 | c.5150G>A p.R1717Q | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as rs761735333, COSV53662569; called by muse, mutect2, varscan2
- TES | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.417); catalogued as COSV100829375; called by muse, mutect2, varscan2
- TESC | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs756764036, COSV100069366; called by muse, mutect2, varscan2
- TET1 | c.6143T>A p.F2048Y | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV101018703; called by muse, mutect2, varscan2
- TEX47 | c.608T>C p.V203A | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs747785460, COSV99787362; called by muse, mutect2, varscan2
- THBS4 | c.130G>C p.G44R | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV100644391; called by muse, mutect2, varscan2
- THSD7A | c.3727G>A p.G1243R | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69856034; called by muse, mutect2, varscan2
- THSD7B | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as rs1457774852, COSV99745022; called by muse, mutect2, varscan2
- TIPIN | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.013); catalogued as COSV99972475; called by muse, mutect2, varscan2
- TLN2 | c.7009G>A p.D2337N | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV100168005; called by muse, mutect2, varscan2
- TMEM132D | c.1775G>A p.G592E | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.755); catalogued as rs759077899, COSV101243019; called by muse, mutect2, varscan2
- TMEM52 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV100205651; called by muse, mutect2, varscan2
- TMEM67 | c.1662G>A p.M554I | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as rs184632089, COSV100019719; called by muse, mutect2, varscan2
- TP53BP1 | c.4214C>T p.P1405L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as COSV99781204; called by muse, mutect2, varscan2
- TP53BP1 | c.3416C>T p.P1139L | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs1299648700, COSV55511267, COSV99781206; called by muse, mutect2, varscan2
- TPR | c.3276T>A p.D1092E | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100824193; called by muse, mutect2, varscan2
- TPTE | c.695G>A p.R232K (on ENST00000618007 / NM_199261.4; = p.R214K on NM_199259.4) | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1460256558; called by muse, mutect2
- TRAF3IP3 | c.8G>A p.S3N | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as rs762916063, COSV99162745; called by muse, mutect2, varscan2
- TRAF3IP3 | c.578A>T p.E193V | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99162761; called by muse, mutect2, varscan2
- TRANK1 | c.6928G>A p.E2310K | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100082136, COSV100084313; called by muse, mutect2, varscan2
- TRIM36 | c.1724T>A p.F575Y | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as COSV99142569; called by muse, mutect2, varscan2
- TRIM51 | c.524G>A p.R175K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.311); catalogued as COSV99793051; called by muse, mutect2
- TRIM60 | c.827G>A p.G276D | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV100594090; called by muse, mutect2, varscan2
- TRIOBP | c.5623C>T p.R1875W (on ENST00000644935 / NM_001039141.3; = p.R162W on NM_007032.5) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778674956, COSV58526126; called by muse, mutect2, varscan2
- TRPM3 | c.3374C>T p.S1125L (on ENST00000357533 / NM_001366142.2; = p.S980L on NM_020952.6) | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs779304187, COSV62581928; called by muse, mutect2, varscan2
- TSPYL6 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100336814; called by muse, mutect2, varscan2
- TTC37 | c.4044_4045del p.C1349Hfs*7 | Frame Shift Del (DEL) | VAF 11/55 reads (20%) | catalogued as rs752381391; called by pindel, varscan2
- TTN | c.67396C>T p.P22466S (on ENST00000591111; = p.P15042S on NM_003319.4) | Missense Mutation (SNP) | VAF 20/56 reads (36%) | PolyPhen probably damaging (0.998); catalogued as COSV100624780; called by muse, mutect2, varscan2
- TTN | c.54884A>C p.H18295P (on ENST00000591111; = p.H10871P on NM_003319.4) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | PolyPhen possibly damaging (0.558); catalogued as COSV100624785; called by muse, mutect2, varscan2
- TTN | c.29614C>T p.P9872S (on ENST00000591111; = p.P8945S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | PolyPhen possibly damaging (0.844); catalogued as COSV100624790; called by muse, mutect2, varscan2
- TTN | c.22366C>T p.H7456Y (on ENST00000591111; = p.H6529Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/64 reads (14%) | PolyPhen benign (0); catalogued as rs777185633, COSV100624791; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBAL3 | c.298C>T p.L100F | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV100990582; called by muse, mutect2, varscan2
- TUBAL3 | c.63G>A p.W21* | Nonsense Mutation (SNP) | VAF 10/94 reads (11%) | catalogued as rs1389639098; called by muse, mutect2
- TUSC3 | c.280C>T p.Q94* | Nonsense Mutation (SNP) | VAF 14/78 reads (18%) | catalogued as rs868472774, COSV101140155; called by muse, mutect2, varscan2
- UBE3A | c.2110C>T p.P704S | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.593); catalogued as COSV51669103; called by muse, mutect2
- UGT3A2 | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99236730; called by muse, mutect2, varscan2
- UNC5D | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as COSV54790681; called by muse, mutect2, varscan2
- UNC5D | c.1367G>A p.G456E | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV99777828; called by muse, mutect2, varscan2
- USH2A | c.7831T>G p.S2611A | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100240290; called by muse, mutect2, varscan2
- USP14 | c.397C>T p.L133F | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1209771623, COSV99864332; called by muse, mutect2, varscan2
- USP14 | c.398T>C p.L133P | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99864333; called by muse, mutect2, varscan2
- USP17L2 | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.191); catalogued as rs867497532, COSV100414690; called by muse, mutect2, varscan2
- USP31 | c.1126C>T p.R376C | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146108628, COSV54858988; called by muse, mutect2, varscan2
- UTP14C | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV101584378; called by muse, mutect2, varscan2
- VPS13C | c.11113C>T p.Q3705* (on ENST00000644861 / NM_020821.3; = p.Q3662* on NM_017684.5) | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | catalogued as COSV99829751; called by muse, mutect2, varscan2
- VPS50 | c.2426T>A p.M809K | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV59917763; called by muse, mutect2, varscan2
- WDR17 | c.3796C>T p.L1266F | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs1228711572, COSV99708082, COSV99708125; called by muse, mutect2, varscan2
- WDR53 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV100218133; called by muse, mutect2, varscan2
- WDR89 | c.742C>A p.H248N | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99962543; called by muse, mutect2, varscan2
- WDR90 | c.671T>C p.F224S | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99553967; called by muse, mutect2, varscan2
- WEE2 | c.1535G>A p.R512K | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.145); catalogued as COSV101187681; called by muse, mutect2, varscan2
- WHAMM | c.1994C>A p.S665Y | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as COSV99725153; called by muse, mutect2
- WNT5B | c.525T>A p.F175L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as COSV100148796; called by muse, mutect2, varscan2
- WSCD1 | c.1300T>A p.S434T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); catalogued as COSV100496748; called by muse, mutect2, varscan2
- WSCD1 | c.1301C>T p.S434F | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV58498376; called by muse, mutect2, varscan2
- XIRP1 | c.3829G>A p.E1277K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs759112662, COSV100453853; called by muse, mutect2, varscan2
- XIRP2 | c.4697G>A p.G1566E (on ENST00000628543; = p.G1741E on NM_152381.6) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54685648; called by muse, mutect2, varscan2
- XPNPEP2 | c.1748G>A p.G583E | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.059); catalogued as COSV64368981; called by muse, mutect2, varscan2
- XPO7 | c.3199C>T p.R1067* | Nonsense Mutation (SNP) | VAF 16/53 reads (30%) | catalogued as rs1189412627, COSV99381897; called by muse, mutect2, varscan2
- YY1AP1 | c.1934C>T p.S645F (on ENST00000295566 / NM_139118.2; = p.S588F on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); catalogued as COSV55124604; called by muse, mutect2, varscan2
- ZBTB20 | c.1295C>T p.S432F (on ENST00000474710 / NM_001164342.2; = p.S359F on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1232823671, COSV100614819; called by muse, mutect2, varscan2
- ZC3H13 | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.433); catalogued as COSV99668709; called by muse, mutect2, varscan2
- ZDBF2 | c.5390C>T p.S1797F | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as rs746979785, COSV100985311; called by muse, mutect2, varscan2
- ZFP30 | c.1352C>T p.S451L | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as rs763001581, COSV100666055; called by muse, mutect2, varscan2
- ZFYVE16 | c.602T>A p.I201N | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100566600; called by muse, mutect2, varscan2
- ZNF274 | c.1333C>T p.P445S (on ENST00000610905; = p.P340S on NM_016324.3) | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV58762941; called by muse, mutect2, varscan2
- ZNF28 | c.1049C>G p.T350S | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.839); catalogued as COSV100354650, COSV60424024; called by muse, mutect2, varscan2
- ZNF334 | c.943C>T p.H315Y | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as rs866569319, COSV61617967; called by muse, mutect2, varscan2
- ZNF354A | c.107G>T p.R36I | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV100234603; called by muse, mutect2, varscan2
- ZNF354B | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV59365227; called by muse, mutect2, varscan2
- ZNF385B | c.998G>A p.G333E | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100416336; called by muse, mutect2, varscan2
- ZNF438 | c.2147C>T p.S716F | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.31); catalogued as COSV59200654; called by muse, mutect2, varscan2
- ZNF544 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | catalogued as COSV99517211; called by muse, mutect2, varscan2
- ZNF592 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV100246046; called by muse, mutect2, varscan2
- ZNF599 | c.1741C>T p.H581Y | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); catalogued as COSV100251264; called by muse, mutect2, varscan2
- ZNF665 | c.1553C>T p.S518L (on ENST00000600412; = p.S583L on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV101128711; called by muse, mutect2, varscan2
- ZNF750 | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs766066825, COSV53960093; called by muse, mutect2, varscan2
- ZNF783 | c.272A>T p.Q91L | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV65185120; called by muse, mutect2, varscan2
- ZNF823 | c.1370C>T p.S457F (on ENST00000341191 / NM_001297610.2; = p.S413F on NM_017507.2) | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.917); catalogued as COSV57876979; called by muse, mutect2, varscan2
- ZNF93 | c.444T>G p.D148E | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.106); catalogued as COSV100652372; called by mutect2, varscan2
- ZSCAN5B | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV100628037; called by muse, mutect2, varscan2
- CCDC85A | c.719_720delinsT p.P240Lfs*71 | Frame Shift Del (DEL) | VAF 11/35 reads (31%) | called by pindel, varscan2*
- CCNA1 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 2/17 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- DCSTAMP | c.1040_1044del p.T347Rfs*5 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | called by mutect2, pindel, varscan2
- DNTTIP2 | c.1106_1109delinsTTG p.T369Ifs*4 | Frame Shift Del (DEL) | VAF 9/83 reads (11%) | called by pindel, varscan2*
- FCGBP | c.9444G>A p.E3148= | Splice Region (SNP) | VAF 10/89 reads (11%) | called by muse, mutect2, varscan2
- HFE | c.206A>T p.E69V | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- IGHV3-49 | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- IGKV1D-42 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- IGKV6-21 | c.253G>A p.G85R | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- LEPR | c.99del p.F33Lfs*83 | Frame Shift Del (DEL) | VAF 17/67 reads (25%) | called by mutect2, pindel*, varscan2
- MYO19 | c.2681G>A p.R894K (on ENST00000614623 / NM_001163735.1; = p.R694K on NM_025109.5) | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NXF5 | n.1165G>A | Splice Region (SNP) | VAF 12/40 reads (30%) | called by muse, mutect2, varscan2
- OR13G1 | c.875G>A p.R292K | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC13A4 | c.1181A>G p.E394G | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ABCA5 | c.4401C>A p.A1467= | Silent (SNP) | VAF 24/99 reads (24%) | catalogued as COSV101201240; called by muse, mutect2, varscan2
- ACTBL2 | c.339C>T p.P113= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV101379400; called by muse, mutect2, varscan2
- ADAM18 | c.1251C>T p.C417= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV99695985; called by muse, mutect2, varscan2
- ADAMTS18 | c.1455C>T p.F485= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs747680539, COSV51405594; called by muse, mutect2, varscan2
- ADAMTS2 | c.3417C>T p.P1139= | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as COSV52372108, COSV99283493; called by muse, mutect2, varscan2
- ADAMTS20 | c.2781G>A p.L927= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as COSV101166372; called by muse, mutect2, varscan2
- ADAMTS9 | c.5265C>T p.F1755= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as rs149034225, COSV55792923; called by muse, mutect2, varscan2
- ADCY8 | c.2553C>T p.L851= | Silent (SNP) | VAF 3/41 reads (7%) | catalogued as rs1006971242, COSV99653686; called by muse, mutect2
- ADCY8 | c.1569G>A p.R523= | Silent (SNP) | VAF 14/101 reads (14%) | catalogued as COSV53894859; called by muse, mutect2, varscan2
- ADRB2 | c.714C>T p.G238= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV60005922; called by muse, mutect2, varscan2
- AFAP1 | c.594C>T p.L198= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as rs1326666933, COSV100631982; called by muse, mutect2, varscan2
- AGRN | c.3141C>T p.S1047= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as rs760391094, COSV65067961; called by muse, mutect2, varscan2
- AKAP12 | c.3510G>A p.E1170= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV99484133; called by muse, mutect2, varscan2
- ANAPC1 | c.3186C>T p.F1062= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV61974313, COSV61974859; called by muse, mutect2, varscan2
- ANKRD33 | c.582C>T p.F194= (on ENST00000340970 / NM_001304459.2; = p.F319= on NM_182608.4) | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs768409817, COSV100001469; called by muse, varscan2
- ANO3 | c.987A>G p.K329= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV99884876; called by muse, mutect2, varscan2
- ANP32D | c.57G>A p.V19= | Silent (SNP) | VAF 15/114 reads (13%) | catalogued as rs866550642, COSV99874371; called by muse, mutect2, varscan2
- AP1G2 | c.768C>T p.I256= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as rs1447250812, COSV99846308; called by muse, mutect2
- ARGFX | c.873C>T p.A291= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as rs1471208046, COSV100544181; called by muse, mutect2, varscan2
- ARHGEF4 | c.345C>T p.L115= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV100388526; called by muse, mutect2, varscan2
- ARSH | c.1671C>T p.I557= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV66962810; called by muse, mutect2, varscan2
- ASIC3 | c.711C>T p.I237= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV52513109; called by muse, mutect2, varscan2
- ASTN1 | c.2370C>T p.F790= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs868503376, COSV56064800, COSV56074819; called by muse, mutect2, varscan2
- ASTN1 | c.2178G>A p.G726= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV56070884, COSV99922716; called by muse, mutect2, varscan2
- ATAD5 | c.4647G>A p.R1549= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as COSV100430154; called by muse, mutect2, varscan2
- ATP10B | c.2949A>C p.P983= | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as COSV100515558, COSV100515641; called by muse, mutect2, varscan2
- ATP4A | c.507C>T p.I169= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as rs1029164457, COSV99382953; called by muse, mutect2, varscan2
- B3GNT7 | c.648C>T p.T216= | Silent (SNP) | VAF 21/122 reads (17%) | catalogued as COSV99805990; called by muse, mutect2, varscan2
- BACH1 | c.1819T>C p.L607= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV99728572; called by muse, mutect2
- BMT2 | c.975C>T p.T325= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as rs1162813552, COSV51775248; called by muse, mutect2, varscan2
- BRINP1 | c.1737C>T p.F579= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as rs376844874; called by muse, mutect2, varscan2
- BUB3 | c.825C>T p.Y275= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV100922257; called by muse, mutect2
- BVES | c.645C>T p.F215= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV58949301; called by muse, mutect2
- C1orf226 | c.660G>A p.R220= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs1434853965, COSV100908151; called by muse, mutect2, varscan2
- C5orf34 | c.1563C>T p.H521= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as COSV100175560; called by muse, mutect2, varscan2
- CACNA1A | c.2583C>T p.F861= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs1222215404, COSV64198369; called by mutect2, varscan2
- CACNA1I | c.3504C>T p.A1168= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as rs751343029, COSV100361201; called by muse, mutect2
- CAMSAP1 | c.1677C>T p.F559= | Silent (SNP) | VAF 29/120 reads (24%) | catalogued as COSV100410325; called by muse, mutect2, varscan2
- CAMSAP3 | c.1377C>T p.I459= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV99351724; called by muse, mutect2, varscan2
- CARMIL2 | c.3591C>T p.P1197= | Silent (SNP) | VAF 10/154 reads (6%) | catalogued as COSV99537942; called by muse, mutect2
- CASP7 | c.672C>T p.S224= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV100614988; called by muse, mutect2
- CASR | c.2739G>A p.R913= (on ENST00000490131; = p.R990= on NM_000388.4) | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs200174909, COSV56134662; called by muse, mutect2
- CCDC170 | c.816G>A p.R272= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs1474802382, COSV53346415; called by muse, mutect2, varscan2
- CCNA1 | c.18C>T p.P6= | Silent (SNP) | VAF 2/17 reads (12%) | catalogued as COSV55224224; called by muse, mutect2
- CD180 | c.813C>T p.L271= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV56519613, COSV99842332; called by muse, mutect2, varscan2
- CD1E | c.24C>T p.F8= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs376989417, COSV63772615; called by muse, mutect2, varscan2
- CD40 | c.171G>A p.T57= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as rs115724543, COSV100953858; called by muse, mutect2, varscan2
- CD8B | c.282G>A p.R94= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as rs753527031, COSV58925488; called by muse, mutect2, varscan2
- CDH2 | c.1509C>T p.I503= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV52278130, COSV99298050; called by muse, mutect2, varscan2
- CDHR2 | c.2172G>A p.T724= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as rs576263638, COSV56136996; called by muse, mutect2, varscan2
- CDK12 | c.2331C>T p.I777= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as rs1318486382, COSV71002042; called by muse, mutect2, varscan2
- CFAP251 | c.2520T>C p.G840= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as rs1453897688, COSV99996354; called by muse, mutect2, varscan2
- CGNL1 | c.882G>A p.R294= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs1257755423, COSV55572399, COSV99848235; called by muse, mutect2, varscan2
- CHD3 | c.3147T>C p.A1049= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV100391522; called by muse, mutect2, varscan2
- CHRNA3 | c.757C>T p.L253= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs200129241, COSV100468529; called by muse, mutect2, varscan2
- CHRNA3 | c.756C>T p.C252= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV58777094; called by muse, mutect2, varscan2
- CHRNB3 | c.621G>A p.K207= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV99251401; called by muse, mutect2, varscan2
- CHRNB3 | c.747C>T p.F249= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV51493373; called by muse, mutect2, varscan2
- CHST9 | c.1104G>A p.G368= | Silent (SNP) | VAF 11/102 reads (11%) | catalogued as COSV52429061; called by muse, mutect2, varscan2
- CHSY3 | c.2062C>T p.L688= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV100519759; called by muse, mutect2, varscan2
- CIB3 | c.384G>A p.L128= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV54165649, COSV99521865; called by muse, mutect2, varscan2
- CLCN4 | c.1158C>T p.P386= | Silent (SNP) | VAF 54/108 reads (50%) | catalogued as COSV66467559; called by muse, mutect2, varscan2
- CLCNKB | c.831C>T p.F277= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs1338271599, COSV100990427; called by muse, mutect2, varscan2
- CLPS | c.30C>T p.V10= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs755917684, COSV99463698; called by muse, mutect2, varscan2
- CNTNAP1 | c.2629C>T p.L877= | Silent (SNP) | VAF 44/111 reads (40%) | catalogued as rs138074241, COSV52848723; called by muse, mutect2, varscan2
- COL4A4 | c.507G>A p.K169= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV100307470; called by muse, mutect2, varscan2
- CPA3 | c.849G>A p.T283= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs200538548, COSV56047209; called by mutect2, varscan2
- CR1 | c.4479C>T p.S1493= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as rs781649483, COSV100887963; called by muse, mutect2, varscan2
- CRB1 | c.1710G>A p.V570= | Silent (SNP) | VAF 19/157 reads (12%) | catalogued as COSV100958043; called by muse, mutect2, varscan2
- CSF1 | c.1402C>T p.L468= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV100294784; called by muse, mutect2, varscan2
- CSMD1 | c.222C>T p.F74= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as COSV101223886; called by muse, mutect2, varscan2
- CSPG4 | c.6033C>T p.V2011= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV100414027; called by muse, mutect2, varscan2
- CTNND2 | c.1569C>T p.L523= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as rs1178953293, COSV100479891; called by muse, mutect2, varscan2
- CUEDC1 | c.945C>T p.T315= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs753567968, COSV100804807; called by muse, mutect2, varscan2
- CWH43 | c.312G>A p.L104= | Silent (SNP) | VAF 28/97 reads (29%) | catalogued as COSV99893833; called by muse, mutect2, varscan2
- CYP2B6 | c.1475G>A p.*492= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as COSV100137710; called by muse, mutect2
- DCTN6 | c.165A>G p.L55= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99645106; called by muse, mutect2
- DCUN1D1 | c.648T>G p.L216= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV99490009; called by muse, mutect2
- DHX36 | c.420T>A p.L140= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV100273846; called by muse, mutect2, varscan2
- DIP2C | c.1971C>T p.A657= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as rs1183083828, COSV99793297; called by muse, mutect2
- DLGAP3 | c.465G>A p.G155= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV99333064; called by muse, mutect2
- DNAH5 | c.13009C>T p.L4337= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV54217227; called by muse, mutect2, varscan2
- DNAH8 | c.13155G>A p.Q4385= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100546736; called by muse, mutect2, varscan2
- DNHD1 | c.18G>A p.R6= | Silent (SNP) | VAF 26/103 reads (25%) | catalogued as rs1219613973, COSV99600750; called by muse, mutect2, varscan2
- DPP6 | c.906C>T p.I302= (on ENST00000377770 / NM_001364500.2; = p.I240= on NM_001936.5) | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as rs763913262, COSV100127386; called by muse, mutect2, varscan2
- DRD1 | c.330C>T p.S110= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV101192511; called by muse, mutect2, varscan2
- DSG1 | c.2493C>T p.G831= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as COSV99936398; called by muse, mutect2, varscan2
- DYRK4 | c.1119C>T p.F373= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as rs866797875, COSV99155345; called by muse, mutect2, varscan2
- EDIL3 | c.1299C>T p.F433= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as COSV99678514; called by muse, mutect2, varscan2
- EDNRA | c.141C>T p.F47= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100163336; called by muse, mutect2, varscan2
- EFCAB6 | c.2766G>A p.R922= | Silent (SNP) | VAF 36/232 reads (16%) | catalogued as COSV99413848; called by muse, varscan2
- ELAPOR2 | c.3078C>T p.S1026= (on ENST00000450689 / NM_001142749.3; = p.S859= on NM_152748.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV99789243; called by muse, mutect2, varscan2
- EPHA8 | c.1947C>T p.V649= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV99385458; called by muse, mutect2, varscan2
- EPHB2 | c.1035C>T p.T345= | Silent (SNP) | VAF 14/101 reads (14%) | catalogued as COSV101007320; called by muse, mutect2, varscan2
- EPHX3 | c.231C>T p.F77= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs1255785078, COSV99651231; called by muse, mutect2, varscan2
- ERCC2 | c.1980G>A p.A660= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs775910108, COSV101228917; called by mutect2, varscan2
- ERO1A | c.1236G>T p.L412= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV101193657; called by muse, mutect2, varscan2
- EVI5L | c.1008C>T p.P336= | Silent (SNP) | VAF 21/108 reads (19%) | catalogued as COSV99563455; called by muse, mutect2, varscan2
- EWSR1 | c.1524C>T p.N508= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV100131979; called by muse, mutect2, varscan2
- EXOC4 | c.2541G>A p.L847= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV54109760; called by muse, mutect2, varscan2
- FAAP20 | c.456G>A p.K152= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs1478169000, COSV101052050; called by muse, mutect2, varscan2
- FAM186B | c.1974G>A p.K658= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs577978845, COSV99219904; called by muse, mutect2, varscan2
- FAM186B | c.1359C>T p.L453= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV57721491, COSV99219909; called by muse, mutect2, varscan2
- FAM209A | c.66C>T p.F22= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as COSV99711480, COSV99711658; called by muse, mutect2, varscan2
- FAP | c.2067C>T p.F689= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV99502433; called by muse, mutect2, varscan2
- FCGR1A | c.687C>T p.F229= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV100977306; called by muse, mutect2, varscan2
- FCRL6 | c.207C>T p.S69= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as COSV100220326; called by muse, varscan2
- FHL2 | c.198C>T p.F66= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100363116; called by muse, mutect2, varscan2
- FLNC | c.3252C>T p.S1084= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs763246279, COSV100368580; called by muse, mutect2, varscan2
- FMN2 | c.3825G>A p.G1275= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV60441644; called by muse, mutect2, varscan2
- FMO3 | c.636C>T p.I212= | Silent (SNP) | VAF 25/113 reads (22%) | catalogued as COSV63008602; called by muse, mutect2, varscan2
- FRY | c.4851A>G p.G1617= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV100969774; called by muse, mutect2, varscan2
- FUT3 | c.186C>T p.T62= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV99744575, COSV99744858; called by mutect2, varscan2
- GBF1 | c.2889C>T p.A963= (on ENST00000369983 / NM_001377137.1; = p.A962= on NM_004193.3) | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV100890627; called by muse, mutect2, varscan2
- GCKR | c.879G>A p.L293= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV99269344; called by muse, mutect2
- GGT7 | c.564C>T p.G188= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as rs376441121; called by muse, mutect2, varscan2
- GJA5 | c.912G>A p.Q304= | Silent (SNP) | VAF 16/119 reads (13%) | catalogued as COSV99605760; called by muse, mutect2, varscan2
- GK2 | c.984T>C p.V328= | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as COSV100726018; called by muse, mutect2, varscan2
- GLI1 | c.1732C>T p.L578= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV99954501; called by muse, mutect2, varscan2
- GLT1D1 | c.717G>A p.V239= (on ENST00000442111 / NM_001366889.1; = p.V159= on NM_144669.3) | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV99897304; called by muse, mutect2, varscan2
- GMPPA | c.204C>T p.F68= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as COSV100354806; called by muse, mutect2, varscan2
- GPR158 | c.2409G>A p.K803= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs746344486, COSV100894010; called by muse, mutect2, varscan2
- GRIK2 | c.2556G>A p.L852= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV100028436; called by muse, mutect2, varscan2
- GRIK4 | c.2373G>A p.K791= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV101483699; called by muse, mutect2, varscan2
- GRM4 | c.2256G>A p.S752= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs1281779944, COSV65221820; called by muse, mutect2, varscan2
- GRM8 | c.1716C>T p.I572= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as rs1050502191, COSV100285097; called by muse, mutect2
- GTF3C3 | c.1528C>T p.L510= | Silent (SNP) | VAF 20/107 reads (19%) | catalogued as COSV99826920; called by muse, mutect2, varscan2
- GYS2 | c.975C>T p.F325= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV99679561, COSV99680108; called by muse, mutect2, varscan2
- HELQ | c.753C>T p.S251= | Silent (SNP) | VAF 28/115 reads (24%) | catalogued as COSV99788031; called by muse, mutect2, varscan2
- HIVEP3 | c.924C>T p.S308= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV99913612; called by muse, mutect2, varscan2
219 further variants in this file (0 protein-altering or splice-affecting, 194 silent, 25 other) are not listed here.
